Gene-level copy-number profile of tumor specimen TCGA-XE-A8GZ-01A from TCGA case TCGA-XE-A8GZ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 42.2 years (15,398 days).
Specimen TCGA-XE-A8GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a6027e3-e5c6-4019-9e36-bb1b8882f3cd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-A8GZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/954b58c5-738b-4c3d-90f6-9faaefcfa924

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 520; copy number 2: 10,775; copy number 3: 27,207; copy number 4: 12,820; copy number 5: 5,013; copy number 6: 1,475; copy number 7: 1,053; copy number 8: 4; copy number 9: 30.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,087 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:76,510,525–97,740,472, 264 genes, copy number 7 (broad region; genes not listed).
- chr7:102,345,746–132,087,992, 480 genes, copy number 7 (broad region; genes not listed).
- chr7:132,784,870–142,802,748, 252 genes, copy number 7–9 (broad region; genes not listed).
- chr14:21,941,128–22,502,292, 74 genes, copy number 7 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
